Somatic mutation profile of tumor specimen TCGA-DX-A8BU-01A (aliquot TCGA-DX-A8BU-01A-11D-A37C-09) from TCGA case TCGA-DX-A8BU, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 58.8 years (21,470 days).
Specimen TCGA-DX-A8BU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eaadd9d-c073-4d3f-a069-a1d614646cf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BU-10A (Blood Derived Normal), aliquot TCGA-DX-A8BU-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9792f357-43d2-4a0a-b791-e17851f55096

The open-access MAF lists 68 somatic variants for this specimen: 47 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 19, Frame Shift Del 5, RNA 1, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLRA1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs281864918, CM992337, COSV99199652; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACR | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs769069119, COSV99334528; called by muse, mutect2
- ADAM28 | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV99739482; called by muse, mutect2, varscan2
- ADAMTS3 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99711788; called by muse, mutect2, varscan2
- ANKRD26 | c.1842A>T p.E614D | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV101063337; called by muse, mutect2
- ARID3C | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV99426763, COSV99427005; called by muse, mutect2, varscan2
- CAND1 | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101604408; called by muse, mutect2, varscan2
- CLSTN2 | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1489606900, COSV71720184, COSV71723684; called by muse, mutect2, varscan2
- CNTNAP3 | c.3410C>T p.A1137V | Missense Mutation (SNP) | VAF 218/426 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as COSV52669000, COSV99905416; called by muse, mutect2, varscan2
- DCDC1 | c.2360A>C p.Q787P | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100663958; called by muse, mutect2
- DLEC1 | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100343142; called by muse, mutect2, varscan2
- FAM169A | c.895A>T p.S299C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.724); catalogued as COSV100998392, COSV65846673; called by muse, mutect2, varscan2
- FBN2 | c.3149C>T p.T1050M | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs150506063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD3 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs770065695; called by muse, mutect2, varscan2
- GMIP | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs896559833, COSV52557345; called by muse, mutect2, varscan2
- KLHL3 | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100553448; called by muse, mutect2, varscan2
- LCT | c.1227C>A p.S409R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99930161; called by muse, mutect2, varscan2
- MMRN1 | c.2903A>T p.E968V | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99307549; called by muse, mutect2, varscan2
- MRGPRF | c.257C>G p.A86G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV100307904; called by muse, mutect2, varscan2
- MUC16 | c.34295C>G p.T11432R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101199983, COSV67495350; called by muse, mutect2, varscan2
- MYLK | c.482C>A p.P161Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100659432; called by muse, mutect2, varscan2
- MYLK | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745692872, COSV100659434, COSV60604248; called by muse, mutect2, varscan2
- NFKB1 | c.621G>A p.M207I (on ENST00000394820 / NM_001382627.1; = p.M208I on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.087); catalogued as COSV99897700; called by muse, mutect2, varscan2
- NR6A1 | c.302A>T p.N101I (on ENST00000487099 / NM_033334.4; = p.N97I on NM_001489.5) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100748660; called by muse, mutect2, varscan2
- NRDC | c.3586A>G p.I1196V | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100543894; called by muse, mutect2, varscan2
- OR4D1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs765156938, COSV99274260; called by muse, mutect2, varscan2
- OR7C2 | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99934604; called by muse, mutect2
- OR8B4 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 15/22 reads (68%) | catalogued as rs1208863555, COSV62069819; called by muse, mutect2, varscan2
- PTPN5 | c.1433T>G p.V478G | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100080196; called by muse, mutect2, varscan2
- PYHIN1 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.377); catalogued as COSV100932391; called by muse, mutect2, varscan2
- SEL1L3 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762938975, COSV53548589; called by muse, mutect2, varscan2
- SIGLEC5 | c.1357T>A p.C453S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99707789; called by muse, mutect2, varscan2
- SLC52A3 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM161104, COSV99448246; called by muse, mutect2, varscan2
- SLIT2 | c.4435C>G p.R1479G | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.16); catalogued as COSV99886242; called by muse, mutect2, varscan2
- TMEM131L | c.4097T>C p.L1366P | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99547952; called by muse, mutect2, varscan2
- TNS3 | c.547G>C p.V183L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV100236153; called by muse, mutect2, varscan2
- TRIM6 | c.413A>T p.Q138L | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV99546687; called by muse, mutect2
- TTC6 | c.1140G>T p.K380N (on ENST00000267368; = p.K1746N on NM_001310135.3) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99942143; called by muse, mutect2
- ZFHX3 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV51714163, COSV99214117; called by muse, mutect2, varscan2
- ZNF569 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1367912384, COSV57594327; called by muse, mutect2, varscan2
- ATRX | c.3695_3699del p.N1232Sfs*15 | Frame Shift Del (DEL) | VAF 15/17 reads (88%) | called by mutect2, varscan2
- CCDC191 | c.1167del p.K389Nfs*30 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.13496_13520del p.N4499Tfs*83 (on ENST00000357337; = p.N4537Tfs*83 on NM_015057.5) | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- RBM28 | c.2209del p.Y737Ifs*53 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- SCUBE2 | c.306_309del p.C102* | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- SP140L | c.1324A>C p.N442H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2
- TP53 | c.766_767insTA p.T256Ifs*90 | Frame Shift Ins (INS) | VAF 40/59 reads (68%) | called by mutect2, pindel, varscan2
- ABCC1 | c.2418C>A p.I806= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100580102; called by muse, mutect2, varscan2
- ADAM2 | c.1452T>C p.C484= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs112394042; called by mutect2, varscan2
- ARSL | c.81A>G p.P27= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV101140705; called by muse, mutect2, varscan2
- CNTNAP4 | c.777C>A p.V259= | Silent (SNP) | VAF 26/31 reads (84%) | catalogued as COSV100272684; called by muse, mutect2, varscan2
- DAPL1 | c.24G>C p.L8= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100007394; called by muse, mutect2, varscan2
- KIR3DL2 | c.861C>T p.H287= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as rs775340833; called by muse, mutect2, varscan2
- KSR2 | c.876G>A p.P292= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV60377531; called by muse, mutect2, varscan2
- KYNU | c.1056G>A p.A352= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs576501053, COSV51587633; called by muse, mutect2, varscan2
- MAP3K4 | c.1645C>T p.L549= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100815596; called by muse, mutect2, varscan2
- MYH8 | c.2403G>A p.R801= | Silent (SNP) | VAF 50/61 reads (82%) | catalogued as rs779259396, COSV101238609; called by muse, mutect2, varscan2
- NEB | c.336A>C p.P112= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV51442093, COSV99426278; called by muse, mutect2, varscan2
- NR2C1 | c.1446A>G p.L482= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs777918858, COSV58012550; called by muse, mutect2, varscan2
- PAGE5 | c.198G>A p.Q66= | Silent (SNP) | VAF 58/60 reads (97%) | catalogued as COSV99215828; called by muse, mutect2, varscan2
- PCDHA5 | c.1386C>T p.F462= | Silent (SNP) | VAF 94/163 reads (58%) | catalogued as COSV65349989; called by muse, varscan2
- PCSK2 | c.366C>T p.N122= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs775687454, COSV52743824; called by muse, mutect2, varscan2
- PRC1 | c.1077A>G p.E359= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100727197; called by muse, mutect2, varscan2
- TCHH | c.778T>C p.L260= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as COSV100915335; called by muse, mutect2, varscan2
- UBR4 | c.1864C>A p.R622= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV100921446; called by muse, mutect2
- ZNF839 | c.1089G>C p.R363= (on ENST00000558850 / NM_001267827.1; = p.R479= on NM_018335.5) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99216164, COSV99216382; called by muse, mutect2, varscan2
- AGAP7P | n.1126A>T | RNA (SNP) | VAF 14/277 reads (5%) | called by muse, mutect2
- CABYR | c.*17-378C>T | Intron (SNP) | VAF 33/36 reads (92%) | catalogued as rs143686609; called by muse, mutect2, varscan2
